Gene-level copy-number profile of tumor specimen TCGA-2G-AAHB-01A from TCGA case TCGA-2G-AAHB, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 36.3 years (13,243 days).
Specimen TCGA-2G-AAHB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23664a4a-f505-42af-9d09-52fd66f88373.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/120c8b3c-57ca-44af-b218-b2bbfebc429d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 2,370; copy number 2: 11,567; copy number 3: 28,758; copy number 4: 11,620; copy number 5: 1,120; copy number 6: 2,733; copy number 7: 657; copy number 8: 29.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,554–71,585, 4 genes: FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–3): AL627309.3.
- chr5:17,597,232–17,643,228, 11 genes: TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4.
- chr11:55,602,360–55,652,854, 3 genes: OR4C11, OR4P4, OR4S2.
- chr11:55,673,536–55,686,160, 3 genes: OR4V1P, OR4P1P, AP006437.1.
- chr22:18,340,145–18,843,399, 24 genes (within-gene range 0–4): GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 686 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,812,628–23,897,335, 33 genes, copy number 7: TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1.
- chr7:39,947,522–40,134,622, 6 genes, copy number 8: AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:62,275,361–62,275,678, 1 gene, copy number 7: AC128676.1.
- chr7:75,416,786–112,521,670, 646 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
